Gene-level copy-number profile of tumor specimen TCGA-XT-AASU-01A from TCGA case TCGA-XT-AASU, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 60.3 years (22,021 days).
Specimen TCGA-XT-AASU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.d70aad03-1eb5-42b1-bb87-12af0d467c11.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XT-AASU-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1b765475-0b93-4696-a849-7a0469a2d385

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 8,020; copy number 2: 47,421; copy number 3: 4,205; copy number 4: 131; copy number 6: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XT-AASU-01A-11D-A39Q-01): tumor purity 0.41, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:33,513,999–34,165,842, 4 genes (within-gene range 0–1): CSMD2, HSPD1P14, HMGB4, CSMD2-AS1.
- chr3:1,730,070–1,730,474, 1 gene: RPL23AP39.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 11 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr22:29,554,808–29,698,598, 3 genes: NIPSNAP1, NF2, RPEP4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:38,094,368–38,360,098, 1 gene, copy number 6 (within-gene range 1–6): AL117339.4.
- chr10:38,247,922–38,762,491, 15 genes, copy number 6: AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1.

Autosomal genes at a single copy (total copy number 1): 5,599. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
